Somatic mutation profile of tumor specimen MMRF_2715_1_BM_CD138pos (aliquot MMRF_2715_1_BM_CD138pos_T1_KHS5U_L14814) from MMRF case MMRF_2715, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 44.2 years (16,127 days).
Specimen MMRF_2715_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b862d18f-5e22-4d42-89d3-e754ef57b829.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2715_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2715_1_PB_WBC_C2_KHS5U_L14835; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f51fb504-b600-47b9-aa98-da28f61ec125

The open-access MAF lists 101 somatic variants for this specimen: 33 protein-altering or splice-affecting, 13 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, 3'UTR 28, Intron 16, Silent 13, 5'UTR 4, 3'Flank 3, RNA 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACYBP | c.455T>C p.I152T | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.405); catalogued as rs1206197330, COSV100871647; called by mutect2, varscan2
- CCNC | c.715G>C p.E239Q | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV58334965; called by muse, mutect2, varscan2
- FREM1 | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs774310234; called by muse, mutect2, varscan2
- IGKJ2 | c.37A>G p.K13E | Missense Mutation (SNP) | VAF 50/140 reads (36%) | catalogued as rs76129343; called by muse, mutect2, varscan2
- IRF7 | c.1127G>A p.G376E (on ENST00000397566; = p.G363E on NM_001572.5) | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1280048947; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LINS1 | c.1789C>T p.P597S | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59080960; called by muse, mutect2, varscan2
- MAGEL2 | c.74G>T p.R25L | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious, low confidence (0); catalogued as rs895771494; called by muse, mutect2, varscan2
- NUP210L | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 83/181 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55144823; called by muse, mutect2, varscan2
- PDZD7 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.823); catalogued as rs551318046; called by muse, mutect2, varscan2
- PRKG1 | c.322C>T p.L108F | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as rs1308723236; called by muse, mutect2
- RAB3GAP1 | c.2054C>T p.S685F | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51483021; called by muse, mutect2
- SGCD | c.653C>G p.A218G (on ENST00000435422 / NM_001128209.2; = p.A219G on NM_000337.5) | Missense Mutation (SNP) | VAF 74/84 reads (88%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV100551160, COSV61919556; called by muse, mutect2, varscan2
- SLC25A29 | c.551G>A p.G184D (on ENST00000359232 / NM_001039355.3; = p.G118D on NM_152333.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs758459894; called by muse, mutect2, varscan2
- SLC5A6 | c.706T>G p.S236A | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT tolerated (0.74); PolyPhen benign (0.01); catalogued as COSV60159605; called by muse, mutect2, varscan2
- TP53 | c.995T>C p.I332T | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV53123312; called by muse, mutect2, varscan2
- TRPS1 | c.2516C>T p.A839V (on ENST00000220888 / NM_001330599.2; = p.A852V on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 103/182 reads (57%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.726); catalogued as COSV55256726, COSV55264261; called by muse, mutect2, varscan2
- CAPNS2 | c.76G>C p.G26R | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.059); called by muse, varscan2
- CAPNS2 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- CDC7 | c.1450T>G p.S484A | Missense Mutation (SNP) | VAF 10/258 reads (4%) | SIFT tolerated (0.57); PolyPhen benign (0.005); called by muse, mutect2
- DOCK4 | c.3110A>T p.Y1037F | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- GDPD4 | c.421A>G p.M141V | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- IGHD2-8 | c.19T>A p.C7S | Missense Mutation (SNP) | VAF 16/21 reads (76%) | called by mutect2, varscan2
- IGKV2-24 | c.136A>C p.S46R | Missense Mutation (SNP) | VAF 96/212 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- KNL1 | c.6481G>A p.E2161K (on ENST00000346991 / NM_170589.5; = p.E2135K on NM_144508.5) | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- MB21D2 | c.617G>T p.G206V | Missense Mutation (SNP) | VAF 72/176 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOC4L | c.206G>A p.G69D | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); called by muse, mutect2
- OGDHL | c.2679G>T p.K893N | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RRM2 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- SYNCRIP | c.553G>T p.A185S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- TGFBI | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNFRSF25 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- TOM1L1 | c.732A>C p.K244N | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ZNF365 | c.147C>G p.F49L | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- ADORA2B | c.313C>T p.L105= | Silent (SNP) | VAF 43/114 reads (38%) | catalogued as rs948955695; called by muse, mutect2, varscan2
- ASTN2 | c.1161G>A p.K387= | Silent (SNP) | VAF 61/220 reads (28%) | called by muse, mutect2, varscan2
- C14orf93 | c.1461C>T p.L487= | Silent (SNP) | VAF 73/156 reads (47%) | called by muse, mutect2, varscan2
- DDHD2 | c.2046A>T p.L682= | Silent (SNP) | VAF 40/89 reads (45%) | called by muse, mutect2, varscan2
- GCN1 | c.4674A>G p.G1558= | Silent (SNP) | VAF 45/57 reads (79%) | called by muse, mutect2, varscan2
- HDAC4 | c.300C>G p.L100= | Silent (SNP) | VAF 29/70 reads (41%) | catalogued as COSV61879780; called by muse, mutect2, varscan2
- MYO1A | c.1809C>T p.D603= | Silent (SNP) | VAF 27/144 reads (19%) | called by muse, mutect2, varscan2
- NLRC5 | c.4074G>A p.L1358= | Silent (SNP) | VAF 33/128 reads (26%) | called by muse, varscan2
- NWD2 | c.4434G>C p.G1478= | Silent (SNP) | VAF 51/270 reads (19%) | called by muse, mutect2, varscan2
- SEMA3F | c.1605G>A p.A535= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs746778401, COSV99137872; called by muse, mutect2, varscan2
- TAS2R38 | c.789C>T p.A263= | Silent (SNP) | VAF 74/163 reads (45%) | catalogued as COSV71885880; called by muse, mutect2, varscan2
- VPS13D | c.11160G>A p.L3720= | Silent (SNP) | VAF 33/77 reads (43%) | called by muse, varscan2
- WNK2 | c.3945C>T p.I1315= | Silent (SNP) | VAF 37/75 reads (49%) | called by muse, mutect2, varscan2
- ABI3BP | c.1577-8507C>T | Intron (SNP) | VAF 63/134 reads (47%) | catalogued as rs1288728213; called by muse, mutect2, varscan2
- ACSS1 | c.*551G>C | 3'UTR (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- AL353743.4 | n.234G>A | RNA (SNP) | VAF 73/196 reads (37%) | called by muse, mutect2, varscan2
- ARMC8 | c.45+787_45+788insG | Intron (INS) | VAF 55/153 reads (36%) | called by mutect2, pindel, varscan2
- ASIC2 | c.555+116672C>A | Intron (SNP) | VAF 28/96 reads (29%) | called by muse, varscan2
- ATRNL1 | c.*45G>A | 3'UTR (SNP) | VAF 59/268 reads (22%) | called by muse, varscan2
- BAZ1B | c.-19C>G | 5'UTR (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- BMPER | c.-123C>T | 5'UTR (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2, varscan2
- CASP14 | c.404-47C>G | Intron (SNP) | VAF 17/72 reads (24%) | called by muse, mutect2, varscan2
- CCDC191 | c.*705G>A | 3'UTR (SNP) | VAF 35/108 reads (32%) | called by muse, mutect2, varscan2
- CCDC7 | chr10:32876557 C>T | 3'Flank (SNP) | VAF 27/172 reads (16%) | catalogued as rs1366283924; called by muse, mutect2, varscan2
- CGNL1 | c.*2137G>A | 3'UTR (SNP) | VAF 67/227 reads (30%) | catalogued as rs1302769350; called by muse, mutect2, varscan2
- COL4A2 | c.477+13A>T | Intron (SNP) | VAF 13/38 reads (34%) | called by muse, mutect2, varscan2
- DCBLD2 | c.*1344C>A | 3'UTR (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- DEK | c.762+5058C>G | Intron (SNP) | VAF 50/194 reads (26%) | called by muse, mutect2, varscan2
- DSCAM | c.*1538C>G | 3'UTR (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2
- ECE2 | c.2259+17A>G | Intron (SNP) | VAF 12/214 reads (6%) | called by muse, mutect2
- ENDOD1 | c.*2862G>C | 3'UTR (SNP) | VAF 40/85 reads (47%) | called by muse, mutect2, varscan2
- FGF10 | c.*1095G>T | 3'UTR (SNP) | VAF 25/83 reads (30%) | called by muse, mutect2, varscan2
- FMN2 | c.1783-72A>C | Intron (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
- GPR3 | c.*447A>T | 3'UTR (SNP) | VAF 27/53 reads (51%) | called by muse, mutect2, varscan2
- HOXD3 | chr2:176173982 C>G | 3'Flank (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2, varscan2
- JAKMIP3 | c.*342G>A | 3'UTR (SNP) | VAF 12/101 reads (12%) | called by muse, mutect2, varscan2
- JAML | c.44-709G>T | Intron (SNP) | VAF 13/31 reads (42%) | called by muse, mutect2, varscan2
- KCNMB3P1 | n.1927del | RNA (DEL) | VAF 57/184 reads (31%) | called by mutect2, pindel, varscan2
- KCNQ3 | c.*90C>A | 3'UTR (SNP) | VAF 57/139 reads (41%) | catalogued as COSV101195870, COSV101196137; called by muse, mutect2, varscan2
- LTN1 | c.*737C>T | 3'UTR (SNP) | VAF 15/81 reads (19%) | called by muse, mutect2, varscan2
- MARCHF1 | c.*879C>G | 3'UTR (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- MUC15 | c.*981G>C | 3'UTR (SNP) | VAF 5/79 reads (6%) | called by muse, mutect2
- MUC19 | chr12:40525416 G>A | 5'Flank (SNP) | VAF 6/133 reads (5%) | called by muse, mutect2
- MX1 | c.731-96G>T | Intron (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- NCAM1 | c.1954-36G>T | Intron (SNP) | VAF 33/74 reads (45%) | catalogued as rs1555123006; called by muse, mutect2, varscan2
- NLRC5 | c.4070+23G>A | Intron (SNP) | VAF 43/176 reads (24%) | called by muse, varscan2
- PAPOLA | c.837-103A>C | Intron (SNP) | VAF 34/87 reads (39%) | called by muse, mutect2, varscan2
- PAPOLA | c.837-102G>T | Intron (SNP) | VAF 34/86 reads (40%) | catalogued as rs5015253; called by muse, mutect2, varscan2
- PDGFD | c.*2018A>C | 3'UTR (SNP) | VAF 45/95 reads (47%) | called by muse, mutect2, varscan2
- PDZD8 | c.*1230C>G | 3'UTR (SNP) | VAF 19/72 reads (26%) | called by muse, mutect2, varscan2
- PRDM16 | c.*1326C>A | 3'UTR (SNP) | VAF 17/163 reads (10%) | called by muse, mutect2, varscan2
- RAB33B | c.*224G>A | 3'UTR (SNP) | VAF 52/102 reads (51%) | called by muse, mutect2, varscan2
- RNF169 | c.*2090G>C | 3'UTR (SNP) | VAF 26/63 reads (41%) | called by muse, mutect2, varscan2
- RPA2 | c.-10C>G | 5'UTR (SNP) | VAF 36/113 reads (32%) | catalogued as rs771702049; called by muse, mutect2, varscan2
- SAMD4A | c.715+85A>G | Intron (SNP) | VAF 14/34 reads (41%) | catalogued as rs1381741547; called by muse, mutect2, varscan2
- SGCD | c.*3458A>G | 3'UTR (SNP) | VAF 12/114 reads (11%) | called by mutect2, varscan2
- SLC13A3 | c.*2049A>T | 3'UTR (SNP) | VAF 29/74 reads (39%) | called by muse, mutect2, varscan2
- SLC39A14 | chr8:22421660 G>C | 3'Flank (SNP) | VAF 20/26 reads (77%) | called by muse, varscan2
- SNX21 | c.*1002T>G | 3'UTR (SNP) | VAF 36/84 reads (43%) | called by muse, mutect2, varscan2
- SNX7 | c.*264G>C | 3'UTR (SNP) | VAF 24/58 reads (41%) | called by muse, mutect2, varscan2
- SPRY3 | c.*4212G>T | 3'UTR (SNP) | VAF 68/377 reads (18%) | called by muse, mutect2, varscan2
- TMEFF2 | c.439+2710A>G | Intron (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2, varscan2
- TXNL1 | chr18:56638676 G>A | 5'Flank (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- USP46 | c.*2596T>A | 3'UTR (SNP) | VAF 32/82 reads (39%) | catalogued as COSV71513100; called by muse, varscan2
- VAX1 | c.*200G>A | 3'UTR (SNP) | VAF 5/17 reads (29%) | catalogued as rs920585806; called by muse, mutect2
- XRCC2 | c.*1335G>A | 3'UTR (SNP) | VAF 47/117 reads (40%) | called by muse, mutect2, varscan2
- ZNF704 | c.*958T>A | 3'UTR (SNP) | VAF 31/105 reads (30%) | called by muse, mutect2, varscan2
- ZPR1 | c.-29A>C | 5'UTR (SNP) | VAF 11/90 reads (12%) | catalogued as rs889421200; called by muse, mutect2, varscan2
